Somatic mutation profile of tumor specimen C3L-04011-04 (aliquot CPT0242880006) from CPTAC case C3L-04011, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.3 years (21,276 days).
Specimen C3L-04011-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1154c84c-2695-461b-81f6-3444c36e6b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04011-31 (Blood Derived Normal), aliquot CPT0242950007; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acde88ef-1165-4e02-8ae3-97aa97e6314d

The open-access MAF lists 82 somatic variants for this specimen: 55 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 25, Nonsense Mutation 4, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1166A>G p.H389R | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs771508494; called by muse, mutect2
- ANKRD12 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as rs777352553; called by muse, mutect2
- ASIC5 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV73332652; called by muse, mutect2
- CCKBR | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 79/473 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1461554621; called by muse, mutect2, varscan2
- CLIC6 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 38/523 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1039748199; called by muse, mutect2
- COL27A1 | c.4060C>T p.R1354* | Nonsense Mutation (SNP) | VAF 47/361 reads (13%) | catalogued as COSV61923307; called by muse, mutect2, varscan2
- GABRA3 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100942603; called by muse, mutect2, varscan2
- IKZF1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs768183030; called by muse, mutect2, varscan2
- LOXHD1 | c.5102C>T p.A1701V (on ENST00000642948; = p.A590V on NM_001145472.3) | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.33); catalogued as rs1164174389, COSV100190357; called by muse, mutect2
- LRP2 | c.5570G>A p.R1857K | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV55568586, COSV55570696; called by muse, mutect2
- LRRC47 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 35/540 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs202080866; called by muse, mutect2
- MBD6 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 300/1465 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV100670428; called by muse, mutect2, varscan2
- MBD6 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 338/1639 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1208663295; called by muse, mutect2, varscan2
- MBD6 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 279/1269 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775674134; called by muse, mutect2, varscan2
- MBD6 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 326/1544 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100851658; called by muse, mutect2, varscan2
- MDN1 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206783600; called by muse, mutect2, varscan2
- MROH2B | c.1986G>C p.E662D | Missense Mutation (SNP) | VAF 99/591 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.215); catalogued as COSV68183618; called by muse, mutect2, varscan2
- MYOCD | c.177G>A p.K59= | Splice Region (SNP) | VAF 21/290 reads (7%) | catalogued as COSV100590809; called by muse, mutect2
- NRK | c.3739C>T p.R1247* | Nonsense Mutation (SNP) | VAF 80/370 reads (22%) | catalogued as COSV99686727; called by muse, mutect2, varscan2
- POGLUT1 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs905479545; called by muse, mutect2, varscan2
- RBMXL3 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 72/599 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs782411507; called by muse, varscan2
- RNF43 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 35/499 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV60419728; called by muse, mutect2
- RPS6KB2 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776029111; called by muse, mutect2, varscan2
- TTN | c.90205G>A p.G30069S (on ENST00000591111; = p.G22645S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | PolyPhen probably damaging (0.999); catalogued as rs770979567; called by muse, mutect2
- TTN | c.4994G>A p.G1665E (on ENST00000591111; = p.G1619E on NM_003319.4) | Missense Mutation (SNP) | VAF 35/526 reads (7%) | PolyPhen probably damaging (1); catalogued as COSV60343736; called by muse, mutect2
- UGT1A6 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV100530370; called by muse, mutect2, varscan2
- ZXDC | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs752175174; called by muse, mutect2
- ACR | c.405C>G p.N135K | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- AGTR2 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 100/505 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- B4GALNT1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 392/1362 reads (29%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.284T>G p.M95R | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CHM | c.1281A>G p.I427M | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUX2 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 169/699 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUX2 | c.1839G>C p.K613N | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DENND4C | c.4309G>C p.D1437H (on ENST00000434457 / NM_001330640.2; = p.D1388H on NM_017925.7) | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNAH9 | c.7151G>A p.G2384E | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- FAM110C | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 16/583 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2
- HUWE1 | c.4726G>A p.E1576K | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IQCD | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 295/1860 reads (16%) | called by muse, mutect2, varscan2
- ITGA4 | c.2423C>A p.T808N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGAL | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- LDB2 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2
- LRP1B | c.6704G>A p.R2235K | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2
- LRRC4C | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA8 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 59/463 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBD6 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 180/882 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO5B | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- NBEAL2 | c.3886G>C p.A1296P | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OBSCN | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51M1 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PIBF1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TENM3 | c.2900T>A p.V967E | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- TFAP2A | c.320C>T p.S107F (on ENST00000482890; = p.S99F on NM_001032280.3) | Missense Mutation (SNP) | VAF 146/532 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TSPYL5 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 65/490 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF700 | c.1230G>T p.R410S | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C6 | c.2187G>A p.E729= | Silent (SNP) | VAF 40/776 reads (5%) | called by muse, mutect2
- CCDC73 | c.570G>A p.R190= | Silent (SNP) | VAF 9/231 reads (4%) | catalogued as rs1479523025, COSV100068130; called by muse, mutect2
- CEMIP2 | c.3534G>A p.P1178= | Silent (SNP) | VAF 28/443 reads (6%) | catalogued as rs142314012, COSV65487935; called by muse, mutect2
- DAB2 | c.384G>A p.V128= | Silent (SNP) | VAF 58/1011 reads (6%) | called by muse, mutect2
- ETV7 | c.498G>A p.G166= | Silent (SNP) | VAF 46/544 reads (8%) | called by muse, mutect2
- FGD4 | c.90C>T p.P30= | Silent (SNP) | VAF 48/380 reads (13%) | called by muse, mutect2, varscan2
- FGFR1 | c.202C>A p.R68= | Silent (SNP) | VAF 43/585 reads (7%) | catalogued as rs775895631, COSV58339475; called by muse, mutect2
- FOXD4L3 | c.702C>T p.G234= | Silent (SNP) | VAF 77/606 reads (13%) | catalogued as rs1554670848; called by muse, mutect2, varscan2
- GBP4 | c.648G>A p.E216= | Silent (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- HECTD4 | c.1131C>T p.S377= | Silent (SNP) | VAF 44/1898 reads (2%) | called by muse, mutect2
- HTR3C | c.612G>T p.T204= | Silent (SNP) | VAF 32/306 reads (10%) | catalogued as COSV59176951; called by muse, mutect2, varscan2
- IGF2R | c.3777C>T p.F1259= | Silent (SNP) | VAF 51/440 reads (12%) | called by muse, mutect2, varscan2
- KRTAP10-8 | c.273C>T p.T91= | Silent (SNP) | VAF 44/534 reads (8%) | catalogued as rs1428441587; called by muse, mutect2
- LY6K | c.12C>T p.L4= | Silent (SNP) | VAF 37/307 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.3183G>A p.E1061= | Silent (SNP) | VAF 30/420 reads (7%) | catalogued as rs1487729754; called by muse, mutect2
- MBD6 | c.972C>T p.L324= | Silent (SNP) | VAF 371/1659 reads (22%) | catalogued as rs1187803586; called by muse, mutect2, varscan2
- NKD2 | c.1014G>A p.G338= | Silent (SNP) | VAF 64/416 reads (15%) | catalogued as rs768316471; called by muse, mutect2, varscan2
- PARP10 | c.2043A>G p.Q681= | Silent (SNP) | VAF 85/410 reads (21%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3162G>A p.R1054= (on ENST00000676171; = p.R1013= on NM_004570.5) | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as rs372691815; called by muse, mutect2, varscan2
- PTPRM | c.3252C>T p.S1084= | Silent (SNP) | VAF 50/336 reads (15%) | called by muse, mutect2, varscan2
- PTPRS | c.516C>T p.F172= | Silent (SNP) | VAF 38/396 reads (10%) | called by muse, mutect2
- SERPINE3 | c.390C>T p.H130= | Silent (SNP) | VAF 24/380 reads (6%) | catalogued as rs767321197, COSV68545037; called by muse, mutect2
- SH3GL2 | c.481T>C p.L161= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as rs773932731; called by muse, mutect2, varscan2
- THSD7A | c.546C>G p.L182= | Silent (SNP) | VAF 38/366 reads (10%) | catalogued as COSV101448526; called by muse, mutect2, varscan2
- USP31 | c.444C>T p.N148= | Silent (SNP) | VAF 30/436 reads (7%) | catalogued as rs1330995091; called by muse, mutect2
- CALN1 | c.*2960del | 3'UTR (DEL) | VAF 38/296 reads (13%) | called by mutect2, pindel, varscan2
- TANGO2 | c.56+230G>A | Intron (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
